Surgical pathology report (de-identified scan), TCGA case TCGA-KH-A6WC, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-KH-A6WC-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: [REDACTED]
Account #: [REDACTED] Date of Procedure: [REDACTED]
DOB: [REDACTED] (Age:) M Date of Receipt: [REDACTED]
Physician: [REDACTED] Date of Report: [REDACTED]
CC: [REDACTED]
Patient Address: [REDACTED]

....

Clinical Diagnosis & History:

Squamous cell carcinoma. Esophageal mass from 31 33 cm. Rule out carcinoma.

Specimens Submitted:

1: Esophagus at 32 cm

DIAGNOSIS:

1. Esophagus, at 32 cm, biopsy:
- Invasive squamous cell carcinoma

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received in formalin, labeled "Esophagus at 32 cm", and consists of 3 fragments of tan soft tissue measuring 0.3-0.4 cm. The specimen is entirely submitted.

Summary of sections:

GI-GI

Summary of Sections:

Part 1: Esophagus at 32 cm

Block	Sect.	Site	PCs
1	GI	3	

** Continued on next page **

ICD-O-3
Carcinoma, squamous cell
Site Middle third & path
esophagus C15.4
Distal third esophagus C15.5
7/25/13

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]
MRN: [REDACTED]
Account #: [REDACTED]

Accession #: [REDACTED]
Physician: [REDACTED]
Service: [REDACTED]
Date of Report: [REDACTED]

Page 2 of 2

**** End of Report ****

II/PA Discrepancy		✓
Case is [REDACTED] QUALIFIED		
Reviewed [REDACTED] Date Reviewed: 7/15/13		

Source: NCI Genomic Data Commons file eb3adb8a-42da-4cd4-ab18-33524f3d212b (TCGA-KH-A6WC.2316F688-42D5-46E4-BE23-F90C5ED76C6E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).